Gene-level copy-number profile of tumor specimen 1105246 from CPTAC case C243048, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Frontal lobe; Tumor grade: G4.
Specimen 1105246: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7643a6c5-cdb2-46bf-b9ad-28753e6db898.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105206 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/afd55c4f-94fd-445b-95f6-f3e82662b5f8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,103; copy number 2: 48,452; copy number 3: 3,525; copy number 4: 220; copy number 5: 52; copy number 9: 46.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 98 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:31,447,741–34,224,952, 48 genes, copy number 5 (within-gene range 4–5): DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7, AC025887.2, WBP11P1, AC025887.1, KLHL14, AC012123.1, AC012123.2, AC090371.2, CCDC178, AC090371.1, AC091198.1, ASXL3, NOL4, Y_RNA.
- chr19:567,210–1,228,431, 46 genes, copy number 9 (within-gene range 3–9): AC009005.1, BSG, HCN2, AC005559.1, POLRMT, AC004449.1, FGF22, RNF126, AC004156.1, FSTL3, PRSS57, RPS2P52, PALM, MISP, AC006273.1, LINC01836, PTBP1, MIR4745, PLPPR3, MIR3187, AZU1, PRTN3, ELANE, CFD, MED16, RNU6-9, R3HDM4, KISS1R, ARID3A, AC005379.1, AC005391.1, WDR18, AC004528.1, GRIN3B, TMEM259, AC004528.2, RNU6-2, CNN2, AC011558.1, ABCA7, ARHGAP45, POLR2E, GPX4, SBNO2, STK11, HMGB2P1.
- chr19:5,158,495–5,340,803, 1 gene, copy number 5 (within-gene range 4–5): PTPRS.
- chr19:5,277,734–5,456,856, 3 genes, copy number 5: RPL32P34, AC005790.1, ZNRF4.

Autosomal genes at a single copy (total copy number 1): 6,103. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
